Somatic mutation profile of tumor specimen TARGET-10-PAPAZD-09A (aliquot TARGET-10-PAPAZD-09A-01D) from TARGET case TARGET-10-PAPAZD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.0 years (2,557 days).
Specimen TARGET-10-PAPAZD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b647b057-d4a1-41b8-a290-188a14ad7d84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPAZD-14A (Bone Marrow Normal), aliquot TARGET-10-PAPAZD-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0edc0d9-0004-40e1-bf40-184d61122b78

The open-access MAF lists 33 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 5, Intron 4, 3'UTR 2, Frame Shift Ins 1, 5'UTR 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 15/95 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM21 | c.1615C>T p.R539C | Missense Mutation (SNP) | VAF 61/327 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs185589078; called by muse, mutect2, varscan2
- C6orf118 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.383); catalogued as rs779270303; called by muse, mutect2, varscan2
- NEUROD2 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.042); catalogued as rs1225173133; called by muse, mutect2, varscan2
- OR14A16 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV62926345; called by muse, mutect2, varscan2
- PRRG3 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as rs765253591; called by muse, mutect2, varscan2
- PTGFRN | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs749956453, COSV101277236; called by muse, mutect2, varscan2
- SETD2 | c.7162dup p.T2388Nfs*41 | Frame Shift Ins (INS) | VAF 24/161 reads (15%) | catalogued as rs1323986990; called by mutect2, pindel, varscan2
- SH3D19 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.782); catalogued as rs1173777533; called by muse, mutect2, varscan2
- TBL1Y | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs748349763; called by muse, mutect2, varscan2
- TENM2 | c.2647C>T p.R883W (on ENST00000518659 / NM_001122679.2; = p.R651W on NM_001080428.3) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs759211946; called by muse, mutect2, varscan2
- TET1 | c.3781G>A p.D1261N | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as rs773967605; called by muse, mutect2
- TTN | c.76874C>T p.A25625V (on ENST00000591111; = p.A18201V on NM_003319.4) | Missense Mutation (SNP) | VAF 22/155 reads (14%) | PolyPhen probably damaging (0.997); catalogued as COSV59901739; called by muse, mutect2, varscan2
- ZNF677 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100447723; called by muse, mutect2, varscan2
- C6orf118 | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- CPEB4 | c.1537C>T p.P513S | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- LRFN2 | c.523C>T p.L175F | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TMEM132D | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- ZBED9 | c.2672A>G p.E891G | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZNF598 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2
- CFAP47 | c.2409A>G p.L803= | Silent (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2, varscan2
- ENPP5 | c.555C>T p.L185= | Silent (SNP) | VAF 23/162 reads (14%) | catalogued as COSV100040222, COSV57910335; called by muse, mutect2, varscan2
- GPM6A | c.129C>T p.F43= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as COSV54537951; called by muse, mutect2, varscan2
- PCDH15 | c.4941G>A p.E1647= (on ENST00000644397 / NM_001354429.2; = p.E1589= on NM_001142771.2) | Silent (SNP) | VAF 25/166 reads (15%) | called by muse, mutect2, varscan2
- TRIM49B | c.1044G>A p.G348= | Silent (SNP) | VAF 26/186 reads (14%) | catalogued as COSV60323317; called by muse, mutect2, varscan2
- GRM6 | c.*1536G>A | 3'UTR (SNP) | VAF 19/106 reads (18%) | catalogued as rs1159684911; called by muse, mutect2, varscan2
- HLA-J | n.913G>A | RNA (SNP) | VAF 8/90 reads (9%) | catalogued as rs1451756268; called by muse, mutect2
- IQCF5 | c.4+28G>A | Intron (SNP) | VAF 21/109 reads (19%) | catalogued as rs995064722; called by muse, mutect2, varscan2
- MMP8 | c.*144G>A | 3'UTR (SNP) | VAF 7/50 reads (14%) | catalogued as rs545394285, COSV99368626; called by muse, mutect2
- MYO5B | c.3131-136C>T | Intron (SNP) | VAF 4/32 reads (13%) | catalogued as rs755654064; called by mutect2, varscan2
- NCAM1 | c.2456+1290C>T | Intron (SNP) | VAF 7/38 reads (18%) | called by mutect2, varscan2
- PYROXD2 | c.147+171C>T | Intron (SNP) | VAF 7/71 reads (10%) | catalogued as rs767395272; called by muse, mutect2, varscan2
- TLR9 | c.-35C>T | 5'UTR (SNP) | VAF 11/87 reads (13%) | catalogued as rs200060413, COSV59725986; called by muse, mutect2, varscan2
